Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A5R7, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A5R7-01A (Primary Tumor).

[page 1 of 2]
ICD 0-3
Astrocytoma, anaplastic
Site ^{RM} ⑤ Brain NOS 9401/3 C71.9
CSCF Brain, Supratentorial C71.0
JW 2/27/13

ANATOMIC PATHOLOGY REPORT

MR# :
ACCT#:
NAME:
AGE:
LOC :
DOCTOR:
COPY TO:

ACCESSION#:

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

The neoplastic cells express IDH1 but are negative for p53. Numerous MIB-1 reactive cells are present with a labeling index of 12.4%.

ADDENDUM DIAGNOSIS:

1-3. Right parietal tumor, including enhancing nodule, biopsy resection;
Anaplastic astrocytoma (grade III)

-- MIB-1 LI = 12.4%

Dictated by

Verified by

ADDENDUM CPT CODES:

ACCESSION#:

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Right parietal tumor FS.
2. Enhancing nodule FS.
3. Right parietal tumor perm.

CLINICAL DIAGNOSIS:

Brain tumor.

GROSS DESCRIPTION:

1. Received fresh for frozen section, labeled with the patient's name and "right parietal tumor," is an irregular portion of tan-white and hemorrhagic soft tissue measuring 1.5 x 1.5 x 0.5 cm. A smear is performed and the entire specimen is frozen as Fl A.

Frozen section diagnosis:

Infiltrating glioma, favor high grade.

The tissue block is subsequently submitted for permanent sectioning.

DATE COLLECTED:

PAGE: 1

DATE RECEIVED:

---- CONTINUED----

[page 2 of 2]
ANATOMIC PATHOLOGY REPORT

MR# :
ACCT#:
NAME:
AGE:
LOC :
DOCTOR:
COPY TO:

ACCESSION#:

NEUROPATHOLOGY REPORT

GROSS DESCRIPTION:

2. Received fresh for frozen section, labeled with the patient's name and "enhancing nodule," is a polypoid portion of tan orange soft tissue measuring 0.7 x 0.5 x 0.5 cm. A smear is performed the entire specimen is frozen as F2A.

Frozen section diagnosis:
High-grade glioma.

The tissue block is subsequently submitted for permanent sectioning.

3. Received in formalin, labeled with the patient's name and "right parietal tumor perm," are multiple irregular fragments of tan-white to red soft tissue measuring in aggregate to 3.0 x 2.0 x 0.6 cm. The entire specimen is submitted in cassettes 3A to 3B.

MICROSCOPIC DESCRIPTION:

1-3. Sections demonstrate a diffusely infiltrative astrocytic neoplasm. Atypia ranges from mild to marked. Cellularity has a similar range. Most of the tumor cells resemble fibrillary or gemistocytic astrocytes. Some cells lack obvious processes and there is a suggestion of perinuclear halos but the overall phenotype of the tumor appears to be astrocytoma. Microvascular proliferation and necrosis are not seen. Unfortunately, specimens one and two are the most cellular. These demonstrate only an occasional mitosis and the frozen section artifact makes identification difficult.

DIAGNOSIS:

(Provisional)

1-3. Right parietal tumor, including enhancing nodule, biopsy and resection;
Consistent with anaplastic astrocytoma, pending additional studies

CPT

CPT:

DATE COLLECTED:

PAGE: 2

DATE RECEIVED:

- END OF REPORT -

Source: NCI Genomic Data Commons file 2e67caef-7b69-4b3c-89db-26b91246c3c7 (TCGA-HT-A5R7.0C8ED6F2-0B6A-4316-A53C-EF42BCB47E39.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).